TCGA case TCGA-XK-AAIR — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: Mayo Clinic Arizona. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/12d2b93e-a033-4b36-ae81-c15879eb40bd

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 75.8 years (27,703 days); Year of diagnosis: 2011; Method of diagnosis: Core Biopsy; AJCC clinical T: T1c; AJCC clinical M: M0; AJCC pathologic T: T2c; AJCC pathologic N: N0; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 8.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 10; Tumor level prostate: Apex / Middle.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 972 days (2.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.09 ng/mL (day 953).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XK-AAIR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 10 mg.
  Slide TCGA-XK-AAIR-01Z-00-DX1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XK-AAIR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XK-AAIR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Ct scan ab pelvis indicator: No; Diagnostic mri performed: No; Lymph nodes examined: Yes; Treatment outcome first course: Complete Remission/Response; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Middle.
- Stage record, Psa: PSA most recent results: 0.09.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 4.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 972 days; disease-specific survival: no event (censored), 972 days; disease-free interval: no event (censored), 972 days; progression-free interval: no event (censored), 972 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XK-AAIR-01A-11D-A41J-01): tumor purity 0.32, ploidy 1.93, whole-genome doublings 0.
